Somatic mutation profile of tumor specimen TCGA-EM-A2P3-01A (aliquot TCGA-EM-A2P3-01A-11D-A202-08) from TCGA case TCGA-EM-A2P3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 47.9 years (17,495 days).
Specimen TCGA-EM-A2P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ffc0e17-02dc-4141-82cb-718e61e927d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2P3-10A (Blood Derived Normal), aliquot TCGA-EM-A2P3-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95f727e6-0d71-4887-a876-308bb072e00b

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- APOBEC2 | c.649_651del p.E217del | In Frame Del (DEL) | VAF 26/85 reads (31%) | catalogued as rs775275042; called by pindel, varscan2
- FLG | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 29/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372282962; called by muse, mutect2
- GRM6 | c.725G>C p.G242A | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV51436227; called by muse, mutect2, varscan2
- PAK5 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs991533102, COSV62023211; called by muse, mutect2, varscan2
- PYGO1 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.528); catalogued as rs766267840, COSV57346854; called by muse, mutect2, varscan2
- SLC7A11 | c.355G>T p.G119C | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762190755, COSV54928847; called by muse, mutect2, varscan2
- WNK2 | c.4663C>G p.P1555A (on ENST00000297954 / NM_001282394.1; = p.P1518A on NM_006648.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV52934378; called by mutect2, varscan2
- CUEDC1 | c.279del p.S94Afs*153 | Frame Shift Del (DEL) | VAF 34/109 reads (31%) | called by mutect2, pindel, varscan2
- IL17REL | c.804C>T p.P268= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV58007831; called by muse, mutect2, varscan2
- SORBS2 | c.204A>G p.K68= (on ENST00000284776 / NM_021069.5; = p.K114= on NM_003603.6) | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV52994076; called by muse, mutect2, varscan2
